CCDI case PBBVUA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/ab8d22d6-45b8-4ebd-82b9-d44c65cec021

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 15.2 years (5,542 days).

Biospecimens (3 samples)
- Sample 0DIW63: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIW6Z: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIW7R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
